Somatic mutation profile of tumor specimen ALCH-B053-TTP1-A (aliquot ALCH-B053-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B053, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.0 years (29,226 days).
Specimen ALCH-B053-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c05acacb-e969-4cea-9c3a-1d5105bfe31b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B053-NB1-A (Blood Derived Normal), aliquot ALCH-B053-NB1-A-2-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a36c5e31-1357-4aad-bd26-ee3a64df3899

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Frame Shift Ins 2, Frame Shift Del 2, RNA 1, Splice Site 1, 3'UTR 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 71/383 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALDH9A1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs777696142; called by muse, mutect2, varscan2
- EPHB1 | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as rs1377760142; called by muse, mutect2, varscan2
- RTN4RL1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs778906681; called by muse, mutect2, varscan2
- UBTFL1 | c.689A>G p.H230R | Missense Mutation (SNP) | VAF 19/539 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1353503238; called by muse, mutect2
- ATP11A | c.1132_1139del p.F378Lfs*7 | Frame Shift Del (DEL) | VAF 58/664 reads (9%) | called by mutect2, pindel
- BRINP3 | c.1975G>T p.G659C | Missense Mutation (SNP) | VAF 102/699 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CAPRIN1 | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.04); called by muse, mutect2
- CEP126 | c.3014dup p.T1006Yfs*5 | Frame Shift Ins (INS) | VAF 18/150 reads (12%) | called by mutect2, pindel, varscan2
- FAT3 | c.1703T>C p.I568T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- ITPR2 | c.6680C>G p.S2227C | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NKX2-1 | c.876_922del p.H292Qfs*101 | Frame Shift Del (DEL) | VAF 9/109 reads (8%) | called by mutect2, pindel
- NKX2-1 | c.515_516dup p.V173Rfs*26 | Frame Shift Ins (INS) | VAF 31/315 reads (10%) | called by mutect2, pindel, varscan2
- PARP8 | c.2378-2A>G p.X793_splice | Splice Site (SNP) | VAF 55/337 reads (16%) | called by muse, mutect2, varscan2
- PCARE | c.2884C>A p.H962N | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2
- SCN2A | c.4892C>T p.A1631V | Missense Mutation (SNP) | VAF 56/672 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2
- AZIN1 | c.1167C>T p.F389= | Silent (SNP) | VAF 28/255 reads (11%) | called by muse, mutect2, varscan2
- CFAP54 | c.1827G>T p.T609= | Silent (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- ERV3-1 | c.1515C>T p.Y505= | Silent (SNP) | VAF 42/268 reads (16%) | called by muse, mutect2, varscan2
- IGHV1-2 | c.96G>A p.K32= | Silent (SNP) | VAF 69/590 reads (12%) | catalogued as rs782507249; called by muse, mutect2, varscan2
- OR4C12 | c.336G>A p.L112= | Silent (SNP) | VAF 37/310 reads (12%) | called by muse, mutect2, varscan2
- SFTPA1 | c.729G>A p.L243= | Silent (SNP) | VAF 20/223 reads (9%) | called by muse, mutect2
- AC116655.1 | n.302C>G | RNA (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- ACADS | c.-45G>T | 5'UTR (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- DAAM2 | c.*2396G>T | 3'UTR (SNP) | VAF 19/483 reads (4%) | called by muse, mutect2
- PARVB | c.712+388G>A | Intron (SNP) | VAF 15/171 reads (9%) | catalogued as rs769395054; called by muse, mutect2
